Somatic mutation profile of tumor specimen MBCProject_2991_T1A_WES (aliquot MBCProject_2991_T1A_WES_1) from CMI case MBCProject_2991, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 65.1 years (23,767 days).
Specimen MBCProject_2991_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72c3dd85-0814-4482-ab30-9a13b02bf8a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2991_SALIVA (Saliva), aliquot MBCProject_2991_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3728311f-59a3-45f0-8041-4a7ec8e03b23

The open-access MAF lists 39 somatic variants for this specimen: 22 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 12, Intron 4, Frame Shift Ins 2, 5'UTR 1, Splice Site 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs147771998; called by muse, mutect2
- CIRBP | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.672); catalogued as rs1315514104; called by muse, mutect2
- HCK | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs202001086; called by muse, mutect2, varscan2
- KCNT2 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246238266; called by muse, mutect2, varscan2
- KRT33B | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs139741254; called by muse, mutect2, varscan2
- MAGIX | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.221); catalogued as COSV66255700; called by muse, mutect2, varscan2
- NF2 | c.431dup p.Y144* | Nonsense Mutation (INS) | VAF 33/199 reads (17%) | catalogued as CI045510, CI983522, COSV58520618; called by mutect2, pindel, varscan2
- PCDHB13 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV53394015, COSV53399236; called by muse, mutect2, varscan2
- TEX55 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs748691005, COSV55211265; called by muse, mutect2, varscan2
- ZNF766 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs371225717; called by muse, mutect2, varscan2
- ASXL3 | c.4221_4223del p.V1408del | In Frame Del (DEL) | VAF 32/141 reads (23%) | called by mutect2, pindel, varscan2
- CASP6 | c.541_542insT p.Q181Lfs*11 | Frame Shift Ins (INS) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- DENND5B | c.2211A>C p.E737D | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GREB1 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- HBM | c.128T>C p.F43S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JHY | c.2200T>C p.S734P | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAGEB5 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MAPK9 | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2
- MYPN | c.1198dup p.Q400Pfs*49 | Frame Shift Ins (INS) | VAF 18/172 reads (10%) | called by mutect2, pindel
- PRR32 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TNN | c.3383G>T p.S1128I | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ZNF280D | c.1411-1G>A p.X471_splice | Splice Site (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2, varscan2
- C6orf141 | c.549G>A p.T183= | Silent (SNP) | VAF 51/222 reads (23%) | catalogued as rs372707029; called by muse, mutect2, varscan2
- CYFIP1 | c.3237C>T p.D1079= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1470909901; called by muse, mutect2, varscan2
- FASTKD5 | c.1569T>C p.I523= | Silent (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- FH | c.1161C>G p.V387= | Silent (SNP) | VAF 46/250 reads (18%) | called by muse, varscan2
- LAMB3 | c.3483C>T p.I1161= | Silent (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- MED16 | c.1458C>T p.Y486= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as rs186638145; called by muse, mutect2, varscan2
- PLXNB3 | c.198C>A p.L66= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- PRPH2 | c.468C>T p.I156= | Silent (SNP) | VAF 58/327 reads (18%) | catalogued as rs761275918, COSV57836592; called by muse, mutect2, varscan2
- PSMD1 | c.327C>A p.T109= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- RSPO3 | c.78G>C p.R26= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs777811963; called by muse, mutect2, varscan2
- UNC13B | c.820C>T p.L274= | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, varscan2
- UPK2 | c.327C>T p.L109= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs972799861, COSV50628884, COSV99875132; called by muse, mutect2, varscan2
- CSTA | c.168+22T>C | Intron (SNP) | VAF 33/155 reads (21%) | catalogued as rs1472103014; called by muse, mutect2, varscan2
- MAP2K3 | c.49+3100C>T | Intron (SNP) | VAF 40/161 reads (25%) | catalogued as rs773592747; called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65807G>A | Intron (SNP) | VAF 20/183 reads (11%) | catalogued as rs950972437; called by muse, mutect2, varscan2
- SP9 | c.-23C>T | 5'UTR (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.915-120C>T | Intron (SNP) | VAF 26/200 reads (13%) | called by muse, mutect2, varscan2
